Somatic mutation profile of tumor specimen 0DPJSZ from CCDI case PBCDTI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.0 years (3,290 days).
Specimen 0DPJSZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af77b7bc-abed-4f90-b8b0-498310df50dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPJSD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c79e15b2-c199-4ed7-9a7f-b4b61c2f4cae

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 1, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RTTN | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 33/500 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753323061; called by muse, mutect2
- SHMT2 | c.118A>G p.N40D | Missense Mutation (SNP) | VAF 262/670 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC22 | c.1428G>A p.T476= | Silent (SNP) | VAF 332/715 reads (46%) | catalogued as rs867095132; called by muse, mutect2, varscan2
- UVSSA | c.*8522A>T | 3'UTR (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- VPS11 | c.-153C>T | 5'UTR (SNP) | VAF 308/698 reads (44%) | called by muse, mutect2, varscan2
